Somatic mutation profile of tumor specimen TCGA-EB-A5SG-06A (aliquot TCGA-EB-A5SG-06A-11D-A30X-08) from TCGA case TCGA-EB-A5SG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.2 years (22,350 days).
Specimen TCGA-EB-A5SG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c8244ca-aa01-4553-9fa3-04dde09c0bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5SG-10A (Blood Derived Normal), aliquot TCGA-EB-A5SG-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/304281d0-42f9-48ee-a319-30dfb7a58447

The open-access MAF lists 294 somatic variants for this specimen: 196 protein-altering or splice-affecting, 90 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 90, Nonsense Mutation 11, Splice Region 3, Intron 3, Splice Site 2, RNA 2, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559563141, COSV61632991; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 26/165 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 4/45 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by mutect2, varscan2
- SPAG1 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 17/150 reads (11%) | catalogued as rs770251775, COSV52560436; ClinVar: pathogenic; called by muse, mutect2
- ABCA12 | c.7208C>T p.A2403V (on ENST00000272895 / NM_173076.3; = p.A2085V on NM_015657.3) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55962180; called by muse, mutect2, varscan2
- ABCC8 | c.3943C>T p.H1315Y | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs751671228, COSV100217534; called by muse, mutect2, varscan2
- AC105001.2 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746601664, COSV59109447; called by muse, mutect2
- ACSBG1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV51907003; called by muse, mutect2, varscan2
- ADAM19 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1194445214, COSV57424556; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4455G>A p.A1485= | Splice Region (SNP) | VAF 8/64 reads (13%) | catalogued as COSV54451635; called by muse, mutect2
- ADH6 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52956483; called by muse, mutect2, varscan2
- AGXT2 | c.1067T>G p.F356C | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51487238; called by muse, mutect2, varscan2
- AMY2A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs1321403510; called by muse, mutect2
- ANAPC1 | c.2143T>C p.Y715H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.305); catalogued as COSV61976690; called by muse, mutect2, varscan2
- ANK3 | c.4241T>A p.F1414Y (on ENST00000280772 / NM_001320874.2; = p.F548Y on NM_001149.3) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55061880; called by muse, mutect2, varscan2
- ANK3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1459523623, COSV55061898; called by muse, mutect2
- ANKRD17 | c.7040C>T p.S2347L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV58221332; called by muse, mutect2, varscan2
- ANKS1B | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61355240; called by muse, mutect2, varscan2
- AREG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765591544, COSV52644609; called by muse, mutect2
- ARID5B | c.3490C>T p.P1164S | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99690078; called by muse, mutect2
- ARSJ | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV59538140; called by muse, mutect2, varscan2
- ASXL3 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV52466787; called by muse, mutect2, varscan2
- ATP10B | c.3199G>A p.D1067N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV59154473; called by muse, mutect2
- BPIFB3 | c.1217+1G>A p.X406_splice | Splice Site (SNP) | VAF 22/184 reads (12%) | catalogued as COSV64957447; called by muse, mutect2, varscan2
- BRMS1L | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333187829, COSV53762160; called by muse, mutect2
- BTN3A1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV50024921; called by muse, mutect2, varscan2
- CAMP | c.362G>A p.R121K (on ENST00000296435; = p.R118K on NM_004345.5) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56482061; called by muse, mutect2, varscan2
- CAPN15 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54836152; called by muse, mutect2, varscan2
- CD33 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV51802248; called by muse, mutect2, varscan2
- CEP72 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53793431; called by muse, mutect2
- CHD3 | c.5075C>G p.P1692R (on ENST00000330494 / NM_001005273.3; = p.P1658R on NM_005852.4) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV57876186; called by muse, mutect2
- CHRNA3 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213960; called by mutect2, varscan2
- CLCN2 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55601785; called by muse, mutect2, varscan2
- CLEC4C | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.932); catalogued as rs1404147167, COSV63582740; called by muse, mutect2, varscan2
- CLTCL1 | c.4640C>T p.A1547V (on ENST00000427926 / NM_007098.4; = p.A1490V on NM_001835.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs782192748, COSV53205954; called by muse, mutect2, varscan2
- COL22A1 | c.4802C>T p.P1601L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs974691796, COSV57340741; called by muse, mutect2, varscan2
- COL5A3 | c.3937G>A p.G1313S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53412244; called by muse, mutect2
- CPO | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150008911; called by muse, mutect2, varscan2
- CSMD3 | c.9667G>A p.G3223R (on ENST00000297405 / NM_001363185.1; = p.G3054R on NM_052900.3) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52203004; called by muse, mutect2, varscan2
- CYP27B1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs774009424, COSV99141585, COSV99141604; called by muse, mutect2
- CYSLTR2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.294); catalogued as rs778797978, COSV56166027; called by muse, mutect2
- DCC | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as rs774540293, COSV59086280, COSV59109601; called by muse, mutect2, varscan2
- DGKD | c.1011G>T p.K337N (on ENST00000264057 / NM_152879.3; = p.K293N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV51053493; called by muse, mutect2, varscan2
- DIO2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.444); catalogued as COSV70444888, COSV70445282; called by muse, mutect2
- DIP2B | c.1811A>T p.K604I | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56585406; called by muse, mutect2, varscan2
- DMC1 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53259514; called by muse, mutect2, varscan2
- DMGDH | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54864832; called by muse, mutect2, varscan2
- DNAH2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV99030301, COSV99318347; called by muse, varscan2
- DNAH2 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.089); catalogued as COSV50022822, COSV99318352; called by muse, mutect2, varscan2
- DNAH5 | c.2534A>G p.Q845R | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV54230870; called by muse, mutect2
- DNAI3 | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV54003209; called by muse, mutect2, varscan2
- DNAJB7 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV53422117; called by muse, mutect2, varscan2
- DNMBP | c.4226C>T p.P1409L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs780193965, COSV60627157; called by muse, mutect2, varscan2
- DSCAM | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs913740674, COSV101260907; called by muse, mutect2
- DSCAM | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs1301121125, COSV68028419; called by muse, mutect2
- EBF2 | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV68778353, COSV68778853, COSV68780833; called by muse, mutect2, varscan2
- ESR2 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50832533; called by muse, mutect2, varscan2
- FAM71B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57229458; called by muse, mutect2, varscan2
- FAM83B | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs779324231, COSV60922890; called by muse, mutect2, varscan2
- FANCD2OS | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55039595; called by muse, mutect2, varscan2
- FAT4 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV67888958; called by muse, mutect2
- FCRL5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV62515498; called by muse, mutect2
- FPR1 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59052424; called by muse, mutect2
- FZD2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.056); catalogued as COSV59528826; called by muse, mutect2, varscan2
- GABRR3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.799); catalogued as rs773953288, COSV72084135; called by mutect2, varscan2
- GALNT15 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 18/155 reads (12%) | catalogued as COSV60217654; called by muse, mutect2, varscan2
- GATA6 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1319693692, COSV52526105; called by muse, mutect2, varscan2
- GBF1 | c.5084C>T p.P1695L (on ENST00000369983 / NM_001377137.1; = p.P1694L on NM_004193.3) | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV64145613; called by muse, mutect2, varscan2
- GIMAP8 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs753699589, COSV56231934; called by muse, mutect2, varscan2
- GLCCI1 | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV56202394, COSV56202440; called by muse, mutect2
- GPC4 | c.935T>G p.M312R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63698205; called by muse, mutect2, varscan2
- GPHN | c.733C>T p.P245S (on ENST00000315266 / NM_001377519.1; = p.P278S on NM_020806.5) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59482472; called by muse, mutect2
- GRAP2 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59995574; called by muse, mutect2, varscan2
- GRID1 | c.1503G>A p.W501* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs779834381, COSV60032878; called by muse, mutect2, varscan2
- GRM6 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51439615; called by muse, mutect2
- HERC1 | c.3532T>C p.F1178L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV71248180; called by muse, mutect2, varscan2
- HMMR | c.564A>C p.Q188H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV62374669; called by muse, mutect2
- HNRNPUL1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149392942, COSV54563196; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57132529; called by muse, mutect2, varscan2
- HSD11B1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54827884; called by muse, mutect2
- ICMT | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV59473768; called by muse, mutect2
- IGSF3 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as rs1472091802, COSV59592009; called by muse, mutect2, varscan2
- IL1RL1 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52116740; called by muse, mutect2
- ILDR1 | c.1621G>A p.G541R (on ENST00000344209 / NM_001199799.2; = p.G497R on NM_175924.4) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56550639; called by muse, mutect2, varscan2
- IRAG1 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs980062384, COSV70211396; called by muse, mutect2, varscan2
- ITSN2 | c.2674C>T p.H892Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as COSV61948549; called by muse, mutect2
- JADE2 | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV50918273; called by muse, mutect2, varscan2
- KCNJ3 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54537394; called by muse, mutect2, varscan2
- KDR | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55757764; called by muse, varscan2
- KIAA1755 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs200662079, COSV54073418; called by muse, mutect2, varscan2
- KIF4B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs541398809, COSV70528412; called by muse, mutect2, varscan2
- KLHL18 | c.603C>T p.V201= | Splice Region (SNP) | VAF 26/138 reads (19%) | catalogued as COSV51746214; called by muse, mutect2, varscan2
- KRT39 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV62917409; called by muse, mutect2, varscan2
- LMTK2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV51997297; called by muse, mutect2
- LRRC7 | c.214C>T p.L72F (on ENST00000651989 / NM_001370785.2; = p.L39F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50474057; called by muse, mutect2
- LRRTM1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54442375; called by muse, mutect2, varscan2
- MAGEB3 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64397229; called by muse, mutect2
- MAGEE2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as rs773363908, COSV64897867; called by muse, mutect2, varscan2
- MAPK15 | c.1582G>C p.V528L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV62028681; called by muse, mutect2, varscan2
- MARCHF7 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52029178; called by muse, mutect2
- MEGF10 | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57250417; called by muse, mutect2, varscan2
- MEGF8 | c.2377C>T p.P793S (on ENST00000251268 / NM_001271938.2; = p.P726S on NM_001410.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs972059706, COSV52088328; called by muse, mutect2, varscan2
- MERTK | c.152T>A p.L51* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54930385; called by muse, mutect2, varscan2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, mutect2, varscan2
- MKRN3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs777359232, COSV58810220; called by muse, mutect2, varscan2
- MSH5 | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV65173435; called by muse, mutect2, varscan2
- MST1R | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV56569732; called by muse, mutect2, varscan2
- MYCT1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65890835; called by muse, mutect2, varscan2
- NBPF3 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV59059912; called by muse, mutect2, varscan2
- NCOR1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51973681, COSV51977934; called by muse, mutect2
- NLGN4X | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV52022068; called by muse, mutect2, varscan2
- OR1F1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs111369312, COSV58961283; called by muse, mutect2, varscan2
- OR4C15 | c.1085C>T p.S362F (on ENST00000314644; = p.S308F on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.509); catalogued as rs566059039, COSV58953283; called by muse, mutect2
- OR51B4 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV66517331; called by muse, mutect2, varscan2
- P2RY12 | c.869A>T p.N290I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56381662; called by muse, mutect2, varscan2
- PAH | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61013690; called by muse, mutect2, varscan2
- PASD1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV64855689; called by muse, mutect2, varscan2
- PC | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100540848; called by muse, mutect2
- PCDH10 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs772263978, COSV52088410; called by muse, mutect2, varscan2
- PCDHA12 | c.1835A>T p.Q612L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as COSV56510132; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCLO | c.11611C>T p.Q3871* | Nonsense Mutation (SNP) | VAF 15/475 reads (3%) | catalogued as COSV61640057; called by muse, mutect2
- PEG3 | c.3235C>T p.H1079Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs1233088344, COSV55636207; called by muse, mutect2
- PER2 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99612257; called by muse, mutect2, varscan2
- PF4V1 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.216); catalogued as rs1267702135, COSV56953513; called by muse, mutect2, varscan2
- PGM2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67938322, COSV67939013; called by muse, mutect2, varscan2
- PI4KA | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1473722732, COSV55413265; called by muse, mutect2
- PLPP4 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV64828204; called by muse, mutect2
- PMM1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53448000; called by muse, mutect2, varscan2
- PPM1H | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV57375048; called by muse, mutect2
- PRB4 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.686); catalogued as COSV54397419; called by muse, mutect2
- PRKAA2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442861086, COSV64804244; called by muse, mutect2
- PRKAA2 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV64804254; called by muse, mutect2, varscan2
- PRKACG | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55249679; called by mutect2, varscan2
- PRKD1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV59572154; called by muse, mutect2, varscan2
- PRR27 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs919027112, COSV100748863; called by muse, mutect2
- RAB3GAP1 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as rs781001414, COSV51483373; called by muse, mutect2, varscan2
- RASGEF1C | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs778277079, COSV63179873; called by muse, mutect2, varscan2
- RGS4 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 22/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63357517; called by muse, mutect2
- RGS6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.066); catalogued as COSV59579870; called by muse, mutect2, varscan2
- RNF123 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs1406917388, COSV59688186; called by muse, mutect2, varscan2
- RNF157 | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV53944869; called by muse, mutect2
- RRP12 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59668363; called by muse, mutect2, varscan2
- RTL6 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV57979711; called by muse, mutect2, varscan2
- RTTN | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as COSV55344655, COSV55346335; called by muse, mutect2
- SART3 | c.1913C>T p.P638L (on ENST00000228284; = p.P620L on NM_014706.4) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs763468222, COSV57207840; called by muse, mutect2
- SCN11A | c.3814-1G>A p.X1272_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV56571711; called by muse, mutect2
- SCN3A | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV51812365; called by muse, mutect2, varscan2
- SH3RF2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV63039372; called by muse, mutect2, varscan2
- SLC12A6 | c.454C>T p.R152C (on ENST00000354181 / NM_001365088.1; = p.R101C on NM_005135.2) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51626900, COSV99272585; called by muse, mutect2, varscan2
- SLC26A7 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV52595265; called by muse, mutect2, varscan2
- SLC4A10 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV55772749; called by muse, mutect2, varscan2
- SLC7A13 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149413280; called by muse, mutect2
- SLC7A3 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV53227793; called by muse, mutect2, varscan2
- SLCO6A1 | c.509A>T p.K170I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV65811051; called by muse, mutect2, varscan2
- SMAD3 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV59284787; called by muse, mutect2
- SOS1 | c.3590C>T p.S1197L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.043); catalogued as COSV67675686; called by muse, mutect2, varscan2
- SPRR2F | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | PolyPhen benign (0.043); catalogued as COSV64206222; called by muse, mutect2
- SPTA1 | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs746992826, COSV63751577, COSV63751790; called by muse, mutect2, varscan2
- SPTA1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs772560248, COSV63751978; called by muse, mutect2
- SSR1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs764743777, COSV55203398; called by muse, mutect2, varscan2
- STX4 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV58268565; called by muse, mutect2, varscan2
- SYNE1 | c.337G>A p.D113N (on ENST00000367255 / NM_182961.4; = p.D120N on NM_033071.3) | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs990137456, COSV55003846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT5 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845925; called by muse, mutect2
- TAFA1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs1359732390, COSV72038948; called by muse, mutect2, varscan2
- TAS2R38 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV71885573; called by muse, mutect2
- TCF23 | c.465G>A p.K155= | Splice Region (SNP) | VAF 24/254 reads (9%) | catalogued as COSV56078549, COSV99940305; called by muse, mutect2
- TLR8 | c.2361G>A p.M787I (on ENST00000218032 / NM_138636.5; = p.M805I on NM_016610.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54318539; called by muse, mutect2, varscan2
- TONSL | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV68048469; called by muse, mutect2, varscan2
- TPP2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs773244873, COSV65750679; called by muse, mutect2, varscan2
- TRERF1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV61672998; called by muse, mutect2
- TRMT44 | c.1238T>G p.F413C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67663337, COSV67664098; called by muse, mutect2, varscan2
- TRPM2 | c.1409G>A p.S470N | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV55970971; called by muse, mutect2, varscan2
- TSPEAR | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV59965957; called by muse, mutect2
- TTN | c.93835C>T p.R31279W (on ENST00000591111; = p.R23855W on NM_003319.4) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs755031142, COSV60114647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.78559G>A p.E26187K (on ENST00000591111; = p.E18763K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | PolyPhen benign (0.163); catalogued as COSV60114698; called by muse, mutect2
- UBQLNL | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs755269814, COSV66493708; called by muse, mutect2, varscan2
- UBXN11 | c.947C>T p.A316V (on ENST00000374221 / NM_183008.2; = p.A283V on NM_145345.2) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1390072919, COSV54624979; called by muse, mutect2
- UNC13C | c.6181C>T p.H2061Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as COSV52880692; called by muse, mutect2, varscan2
- UNC79 | c.1054G>A p.D352N (on ENST00000393151 / NM_001346218.2; = p.D175N on NM_020818.5) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV56391766; called by muse, mutect2, varscan2
- WSCD2 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV54584094; called by muse, mutect2, varscan2
- XIRP1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61137520; called by muse, mutect2, varscan2
- Z83844.2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60928379; called by muse, mutect2, varscan2
- ZC2HC1A | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs923645398, COSV55667851, COSV55668937; called by muse, mutect2, varscan2
- ZFAND4 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.071); catalogued as COSV60859470, COSV60861476; called by muse, mutect2, varscan2
- ZFPM2 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409008207, COSV65874068; called by muse, mutect2
- ZNF14 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59849927; called by muse, mutect2, varscan2
- ZNF471 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57291666; called by muse, mutect2
- ZNF518B | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV58722982; called by muse, mutect2, varscan2
- ZNF530 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.861); catalogued as rs267605730, COSV60531746; called by muse, mutect2, varscan2
- ZNF560 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.351); catalogued as COSV56868466, COSV56871346; called by muse, mutect2, varscan2
- ZNF606 | c.2017A>G p.I673V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV58706205; called by muse, mutect2
- ZNF638 | c.4553C>T p.P1518L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.17); catalogued as rs750839888, COSV100039366; called by muse, mutect2, varscan2
- ZNF678 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV59383958; called by muse, mutect2
- ZNF781 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV62200558, COSV62200789; called by muse, mutect2, varscan2
- FAM126A | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCA12 | c.4986G>A p.L1662= (on ENST00000272895 / NM_173076.3; = p.L1344= on NM_015657.3) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV55952841, COSV55962197; called by muse, mutect2
- ACSM2A | c.1041G>A p.E347= (on ENST00000219054; = p.E268= on NM_001308169.2) | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as rs1185082274, COSV54585587; called by muse, mutect2
- AGRN | c.3012C>T p.L1004= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs749392554, COSV65070126; called by muse, mutect2, varscan2
- ARHGEF12 | c.3582T>C p.S1194= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV63105295; called by mutect2, varscan2
- ARID5B | c.3489C>T p.Y1163= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV54414269; called by muse, mutect2
- ATP8A1 | c.2049C>T p.I683= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs1427556593, COSV52536983; called by muse, mutect2
- ATXN7L2 | c.51G>A p.R17= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1048884188, COSV63993849; called by muse, mutect2
- BCAS4 | c.360C>T p.F120= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs774255921, COSV52812060; called by mutect2, varscan2
- BOC | c.2568G>C p.L856= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV56352365; called by muse, mutect2, varscan2
- BTAF1 | c.1410C>T p.P470= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99795558; called by muse, mutect2, varscan2
- C2orf16 | c.1308C>T p.L436= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV68646268; called by muse, mutect2
- CACNA1D | c.5829C>T p.F1943= (on ENST00000350061 / NM_001128840.3; = p.F1963= on NM_000720.4) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs775572299, COSV55450081; called by muse, mutect2, varscan2
- CACNA1H | c.2202C>T p.V734= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1222128472, COSV100670642, COSV61992885; called by muse, mutect2
- CCER1 | c.939G>A p.E313= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1210919662, COSV62647225; called by muse, mutect2, varscan2
- CD163L1 | c.2124G>A p.Q708= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV58017621; called by muse, varscan2
- CHRDL1 | c.1089G>A p.E363= (on ENST00000372045; = p.E369= on NM_145234.4) | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV54325847; called by muse, mutect2, varscan2
- CHRNA3 | c.1470G>A p.G490= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs762458163, COSV55138019; called by muse, mutect2, varscan2
- COL7A1 | c.4041G>A p.G1347= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV60396405; called by muse, mutect2, varscan2
- CRYBA2 | c.348C>T p.F116= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs754826788, COSV55388229; called by muse, mutect2, varscan2
- CSN2 | c.447G>A p.L149= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs376566334; called by muse, mutect2, varscan2
- CYP2C8 | c.336C>T p.I112= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV64876044; called by muse, mutect2, varscan2
- CYP4F2 | c.747C>T p.L249= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs892604604, COSV50001501; called by muse, mutect2, varscan2
- DDX18 | c.1407C>T p.F469= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs1166083927, COSV54307069; called by muse, mutect2, varscan2
- DNAH5 | c.6475C>T p.L2159= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV54230860; called by muse, mutect2
- DNAH9 | c.6772C>T p.L2258= | Silent (SNP) | VAF 13/220 reads (6%) | catalogued as COSV52353798; called by muse, mutect2
- DRD5 | c.483C>T p.V161= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs1423860367, COSV58578645; called by muse, mutect2
- DSCAM | c.4851G>A p.R1617= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs989761654, COSV101260906; called by muse, mutect2
- DSCAM | c.3993G>A p.T1331= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1201000597, COSV68028413; called by muse, mutect2
- ERAP2 | c.2811G>A p.T937= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs778781386, COSV65940003; called by muse, mutect2, varscan2
- GABRA6 | c.147G>A p.P49= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs187766196, COSV50883260; called by muse, mutect2, varscan2
- GAD2 | c.1722G>A p.L574= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1421718884, COSV52159326; called by muse, mutect2, varscan2
- GAK | c.2823C>T p.A941= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV58505524; called by muse, mutect2
- GIMAP8 | c.114C>T p.S38= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV56231927; called by muse, mutect2, varscan2
- GNA12 | c.741C>T p.S247= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV51741908; called by muse, mutect2, varscan2
- HTATSF1 | c.1734T>C p.G578= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV54479269; called by muse, mutect2
- HTR3E | c.952C>T p.L318= (on ENST00000415389 / NM_001256613.1; = p.L333= on NM_182589.2) | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs752491087, COSV58947265; called by muse, mutect2, varscan2
- IGHV3-35 | c.228G>A p.R76= | Silent (SNP) | VAF 24/239 reads (10%) | called by muse, mutect2, varscan2
- IGKV1D-8 | c.192A>G p.K64= | Silent (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- IL11RA | c.670C>T p.L224= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs780533269, COSV52405184; called by muse, mutect2, varscan2
- IL2RB | c.1098C>T p.F366= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs546895176, COSV53426781; called by muse, mutect2, varscan2
- IRF8 | c.1254C>T p.F418= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV51898302; called by muse, mutect2
- ITM2C | c.640C>T p.L214= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100419592, COSV58399571; called by muse, mutect2, varscan2
- KLF17 | c.414C>T p.P138= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV64856448; called by muse, mutect2, varscan2
- LY6K | c.246G>A p.A82= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs782387825, COSV52832165; called by muse, mutect2
- MAGEA10 | c.249T>G p.P83= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as COSV54884290; called by muse, mutect2, varscan2
- MARCO | c.1041G>A p.L347= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as COSV59055260; called by muse, mutect2, varscan2
- MRPL47 | c.36A>G p.R12= | Silent (SNP) | VAF 21/168 reads (13%) | catalogued as rs1490249528, COSV52020579; called by muse, mutect2, varscan2
- MYH8 | c.505T>C p.L169= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as rs1445708977, COSV67966440; called by muse, mutect2, varscan2
- MYO18B | c.7545C>T p.I2515= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs771063098, COSV59126656; called by muse, mutect2, varscan2
- NFRKB | c.381C>T p.C127= (on ENST00000446488 / NM_001143835.2; = p.C140= on NM_006165.3) | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV58758463; called by muse, mutect2, varscan2
- NLRC4 | c.828C>T p.I276= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs774076495, COSV61593036; called by muse, mutect2, varscan2
- NLRP4 | c.72G>A p.R24= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs1357192821, COSV56715473; called by muse, mutect2
- OPN1LW | c.390C>T p.G130= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV64064478; called by muse, mutect2, varscan2
- OR10K1 | c.735C>A p.L245= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV56872346, COSV99194093; called by muse, mutect2, varscan2
- OR13C4 | c.663C>T p.I221= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV52926886; called by muse, mutect2, varscan2
- OR1M1 | c.318C>T p.F106= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV70036977; called by muse, mutect2, varscan2
- OR2W3 | c.555C>T p.I185= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV64457117; called by muse, mutect2, varscan2
- OR6C76 | c.186G>A p.R62= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100094028, COSV60388502; called by muse, mutect2
- OR8H1 | c.36C>T p.F12= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV57294423; called by muse, mutect2, varscan2
- PC | c.1338C>T p.A446= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100540849; called by muse, mutect2
- PCDH10 | c.1291C>T p.L431= | Silent (SNP) | VAF 25/329 reads (8%) | catalogued as COSV52096112; called by muse, mutect2
- PCDHB6 | c.255A>T p.L85= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV50701018; called by muse, mutect2
- PEAR1 | c.339T>A p.R113= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV52773635; called by muse, mutect2, varscan2
- PIGV | c.471C>T p.L157= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV50292317; called by muse, mutect2, varscan2
- POFUT2 | c.801C>T p.I267= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs146423023, COSV57959358; called by muse, mutect2, varscan2
- PRR27 | c.252C>T p.F84= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as COSV100748861; called by muse, mutect2
- PRRC2C | c.2031C>T p.F677= (on ENST00000367742; = p.F675= on NM_015172.4) | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as rs1395126339, COSV58903986; called by muse, mutect2, varscan2
- PTPN13 | c.6951C>T p.I2317= (on ENST00000411767 / NM_080683.3; = p.I2298= on NM_006264.3) | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV57409118, COSV57412011; called by muse, mutect2, varscan2
- RSPH6A | c.843G>A p.R281= | Silent (SNP) | VAF 24/190 reads (13%) | catalogued as COSV55572531; called by muse, mutect2, varscan2
- SEMA4A | c.2112C>T p.A704= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- SENP8 | c.534C>T p.F178= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV61767980, COSV61768044; called by muse, mutect2, varscan2
- SLC12A5 | c.1074C>T p.F358= (on ENST00000454036 / NM_001134771.2; = p.F335= on NM_020708.5) | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs755725158, COSV54794811; called by muse, mutect2
- SLC22A25 | c.783C>T p.L261= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV60596558; called by muse, mutect2, varscan2
- SPTB | c.2925G>A p.K975= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs770606693, COSV67632531; called by mutect2, varscan2
- SYT5 | c.432G>A p.S144= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1044487634, COSV62829625; called by muse, mutect2
- TBC1D24 | c.351C>T p.I117= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV53546813; called by muse, mutect2, varscan2
- TBC1D28 | c.315G>A p.A105= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs201514885, COSV61507251, COSV61507958; called by muse, mutect2
- TC2N | c.990C>T p.T330= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV61747198; called by muse, mutect2, varscan2
- TFEC | c.243C>T p.D81= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV55401728; called by muse, mutect2
- TGM4 | c.1473C>T p.T491= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs142547927; called by muse, mutect2, varscan2
- TMEM63B | c.2115C>T p.F705= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV52479774; called by muse, mutect2
- TPRG1 | c.807C>T p.A269= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61465593; called by muse, mutect2, varscan2
- TRAJ27 | c.27C>T p.T9= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs567176866; called by muse, mutect2, varscan2
- TRHDE | c.1638C>T p.F546= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV53833098, COSV53847881; called by muse, mutect2, varscan2
- TRPS1 | c.1951C>T p.L651= (on ENST00000220888 / NM_001330599.2; = p.L664= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV55244331; called by muse, mutect2, varscan2
- VRK1 | c.1190A>G p.*397= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53709750; called by muse, mutect2, varscan2
- ZNF354C | c.858C>T p.T286= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV59608548; called by muse, mutect2
- ZNF366 | c.714C>T p.I238= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV59216153; called by muse, mutect2, varscan2
- ZNF536 | c.2640C>T p.V880= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV62825882; called by muse, mutect2
- ZNF555 | c.1422C>T p.H474= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV62073310; called by muse, mutect2
- AFDN | c.4812+41C>T | Intron (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- ARPP21 | c.2032+583C>T | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99492592; called by muse, mutect2
- DNAH8 | chr6:38723052 G>A | 5'Flank (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100546477, COSV59452640; called by muse, mutect2, varscan2
- IVNS1ABP | c.*1C>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100832799; called by muse, mutect2
- MIR544A | n.38C>T | RNA (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- MIR587 | n.90C>T | RNA (SNP) | VAF 5/42 reads (12%) | catalogued as rs782588201; called by muse, mutect2, varscan2
- MOB3C | c.-31C>A | 5'UTR (SNP) | VAF 11/94 reads (12%) | catalogued as COSV54719482; called by muse, mutect2, varscan2
- UPB1 | c.364+291C>T | Intron (SNP) | VAF 19/190 reads (10%) | catalogued as COSV100387235; called by muse, mutect2, varscan2
